Somatic mutation profile of tumor specimen TCGA-CC-A5UD-01A (aliquot TCGA-CC-A5UD-01A-11D-A28X-10) from TCGA case TCGA-CC-A5UD, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 45.7 years (16,702 days).
Specimen TCGA-CC-A5UD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5e6019de-7364-4a22-8735-daa23977d1ab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CC-A5UD-10A (Blood Derived Normal), aliquot TCGA-CC-A5UD-10A-01D-A28X-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ba3950ed-b704-4edc-a5f9-f17987284042

The open-access MAF lists 215 somatic variants for this specimen: 158 protein-altering or splice-affecting, 51 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 135, Silent 51, Nonsense Mutation 12, Frame Shift Del 5, Splice Site 4, Intron 3, RNA 2, Translation Start Site 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.98C>A p.S33Y | Missense Mutation (SNP) | VAF 41/137 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KMT2A | c.3301C>T p.R1101* | Nonsense Mutation (SNP) | VAF 40/112 reads (36%) | catalogued as rs886041856, COSV63291301; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.634+1G>T p.X212_splice | Splice Site (SNP) | VAF 10/14 reads (71%) | hotspot (GDC flag); catalogued as CS110219, CS1314438, COSV64295775, COSV64297457, COSV64302278; called by muse, mutect2, varscan2
- TP53 | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 58/76 reads (76%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912654, CM137621, COSV52667015, COSV52676009, COSV52752314, COSV53205488; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, varscan2
- ABCB5 | c.1556G>T p.G519V (on ENST00000404938 / NM_001163941.2; = p.G74V on NM_178559.6) | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99329201; called by mutect2, varscan2
- ABCB5 | c.2624A>T p.K875M (on ENST00000404938 / NM_001163941.2; = p.K430M on NM_178559.6) | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99329207; called by muse, mutect2, varscan2
- ABCC4 | c.1785G>C p.Q595H | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as COSV100972689; called by muse, mutect2, varscan2
- ABHD16A | c.557A>T p.E186V | Missense Mutation (SNP) | VAF 49/62 reads (79%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.446); catalogued as COSV101013320; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2747A>T p.Q916L | Missense Mutation (SNP) | VAF 51/63 reads (81%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV101002017; called by muse, varscan2
- ADCY3 | c.152G>T p.R51L | Missense Mutation (SNP) | VAF 39/131 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.06); catalogued as COSV53165115, COSV99568914; called by muse, mutect2, varscan2
- ADORA3 | c.284A>T p.H95L | Missense Mutation (SNP) | VAF 78/183 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as COSV99598853; called by muse, mutect2, varscan2
- AGAP4 | c.1277G>A p.C426Y | Missense Mutation (SNP) | VAF 51/59 reads (86%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV101432691; called by muse, mutect2, varscan2
- AKAP17A | c.1060G>T p.E354* | Nonsense Mutation (SNP) | VAF 35/59 reads (59%) | catalogued as COSV100002410; called by muse, mutect2, varscan2
- ALMS1 | c.4372G>T p.A1458S | Missense Mutation (SNP) | VAF 72/115 reads (63%) | SIFT tolerated (0.32); PolyPhen benign (0.059); catalogued as COSV100043320; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.6631A>T p.N2211Y | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV99784071; called by muse, mutect2, varscan2
- ANO9 | c.1199T>A p.V400E | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100241158; called by muse, mutect2, varscan2
- ARID1A | c.6640A>T p.S2214C | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100252795; called by muse, mutect2, varscan2
- ARX | c.143A>T p.Q48L | Missense Mutation (SNP) | VAF 38/45 reads (84%) | SIFT deleterious (0.01); PolyPhen benign (0.212); catalogued as COSV100984073; called by muse, mutect2, varscan2
- ATM | c.655T>A p.C219S | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV99591134; called by muse, mutect2, varscan2
- B3GALNT1 | c.648A>T p.R216S | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as CM1314789, COSV100252125; called by muse, mutect2, varscan2
- BRD7 | c.826A>T p.R276* | Nonsense Mutation (SNP) | VAF 36/41 reads (88%) | catalogued as COSV101165035; called by muse, varscan2
- BRWD3 | c.1058A>T p.E353V | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.627); catalogued as COSV100956372; called by muse, mutect2
- C8orf58 | c.43G>T p.G15W | Missense Mutation (SNP) | VAF 40/60 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99254733; called by muse, mutect2, varscan2
- CARD11 | c.422A>T p.Q141L | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.674); catalogued as COSV100712264; called by muse, mutect2, varscan2
- CCDC88C | c.1469A>T p.E490V | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs778090862, COSV101106024; called by muse, mutect2, varscan2
- CCN3 | c.734T>A p.M245K | Missense Mutation (SNP) | VAF 69/172 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as COSV99423255; called by muse, mutect2, varscan2
- CCR1 | c.842T>A p.L281Q | Missense Mutation (SNP) | VAF 71/122 reads (58%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.981); catalogued as COSV99946782; called by muse, mutect2, varscan2
- CCR7 | c.581T>A p.L194H | Missense Mutation (SNP) | VAF 70/127 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV99878785; called by muse, varscan2
- CEP128 | c.2936T>G p.L979R | Missense Mutation (SNP) | VAF 36/64 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99825604; called by muse, mutect2, varscan2
- CFAP91 | c.1823G>A p.R608Q | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1007945476, COSV56340117; called by muse, mutect2, varscan2
- CHEK1 | c.1009A>T p.K337* | Nonsense Mutation (SNP) | VAF 35/69 reads (51%) | catalogued as COSV99629828; called by muse, mutect2, varscan2
- CHL1 | c.571G>T p.A191S | Missense Mutation (SNP) | VAF 166/322 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.218); catalogued as COSV56595004, COSV99851945; called by muse, mutect2, varscan2
- CLCN7 | c.344A>T p.N115I | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.289); catalogued as COSV99247552; called by muse, mutect2, varscan2
- CMYA5 | c.11270A>T p.E3757V | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101484271; called by muse, mutect2, varscan2
- CNOT4 | c.781A>T p.K261* | Nonsense Mutation (SNP) | VAF 28/59 reads (47%) | catalogued as COSV100212054; called by muse, mutect2, varscan2
- CRABP2 | c.92A>T p.K31M | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.449); catalogued as COSV100957573; called by muse, mutect2, varscan2
- CUBN | c.10189A>T p.R3397* | Nonsense Mutation (SNP) | VAF 64/231 reads (28%) | catalogued as COSV100913281; called by muse, mutect2, varscan2
- DEF6 | c.635A>T p.E212V | Missense Mutation (SNP) | VAF 71/86 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100359484; called by muse, mutect2, varscan2
- DNAH2 | c.7684A>G p.I2562V | Missense Mutation (SNP) | VAF 55/65 reads (85%) | SIFT tolerated (0.1); PolyPhen benign (0.148); catalogued as rs1567714402, COSV101209527; called by muse, mutect2, varscan2
- DRC3 | c.1214G>C p.C405S | Missense Mutation (SNP) | VAF 37/173 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV100572793, COSV58267232; called by muse, varscan2
- DTNB | c.1048A>G p.M350V | Missense Mutation (SNP) | VAF 72/105 reads (69%) | SIFT tolerated (0.52); PolyPhen benign (0.01); catalogued as rs981185581, COSV99977837; called by muse, mutect2, varscan2
- EIF2B2 | c.86G>C p.R29P | Missense Mutation (SNP) | VAF 63/202 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.012); catalogued as COSV99837752, COSV99837764; called by muse, varscan2
- EIF4G1 | c.1178C>G p.P393R (on ENST00000346169 / NM_198241.3; = p.P197R on NM_004953.5) | Missense Mutation (SNP) | VAF 90/145 reads (62%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as rs756637859, COSV100072185; called by muse, mutect2, varscan2
- ELFN2 | c.555C>A p.N185K | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101297611; called by muse, mutect2, varscan2
- ELL2 | c.482-1G>C p.X161_splice | Splice Site (SNP) | VAF 32/82 reads (39%) | catalogued as COSV99427762; called by muse, mutect2, varscan2
- EPPK1 | c.4127A>T p.Q1376L | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782660781, COSV101599924; called by muse, mutect2, varscan2
- ERBB4 | c.344A>T p.Y115F | Missense Mutation (SNP) | VAF 55/89 reads (62%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.606); catalogued as COSV99629901; called by muse, mutect2, varscan2
- ERCC6L | c.3465C>A p.N1155K | Missense Mutation (SNP) | VAF 36/45 reads (80%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV100559224; called by muse, mutect2, varscan2
- ERN2 | c.1523A>T p.E508V | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as COSV99892132; called by muse, mutect2, varscan2
- FBXL7 | c.668A>T p.Y223F | Missense Mutation (SNP) | VAF 50/226 reads (22%) | SIFT tolerated (0.65); PolyPhen benign (0.133); catalogued as COSV100310511; called by muse, mutect2, varscan2
- FOLR3 | c.149A>C p.E50A | Missense Mutation (SNP) | VAF 67/194 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.873); catalogued as COSV100281838; called by muse, mutect2, varscan2
- FOLR3 | c.646T>A p.S216T | Missense Mutation (SNP) | VAF 51/121 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as COSV100281839; called by muse, mutect2, varscan2
- FRK | c.916A>T p.T306S | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101606675; called by muse, mutect2, varscan2
- GALK1 | c.244G>T p.A82S | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.059); catalogued as COSV99849570; called by muse, mutect2, varscan2
- GLI3 | c.568T>A p.F190I | Missense Mutation (SNP) | VAF 51/153 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as COSV101229981; called by muse, mutect2, varscan2
- GLT8D2 | c.210T>A p.N70K | Missense Mutation (SNP) | VAF 88/145 reads (61%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.475); catalogued as COSV100674158; called by muse, mutect2, varscan2
- GRXCR1 | c.773T>A p.M258K | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT tolerated (1); PolyPhen probably damaging (0.916); catalogued as COSV101295734; called by muse, mutect2, varscan2
- HDHD3 | c.641C>T p.P214L | Missense Mutation (SNP) | VAF 56/95 reads (59%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV99445066, COSV99445068; called by muse, mutect2, varscan2
- HECTD4 | c.4210A>T p.M1404L | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV100296162; called by muse, mutect2, varscan2
- IFNW1 | c.210G>T p.Q70H | Missense Mutation (SNP) | VAF 40/50 reads (80%) | SIFT tolerated (0.08); PolyPhen benign (0.36); catalogued as COSV66522151, COSV66522170; called by muse, mutect2, varscan2
- ITGA9 | c.3069G>C p.E1023D | Missense Mutation (SNP) | VAF 44/143 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV99293653; called by muse, varscan2
- ITIH4 | c.2627G>T p.G876V | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99819713; called by muse, mutect2, varscan2
- KCNIP4 | c.58G>A p.G20S | Missense Mutation (SNP) | VAF 68/310 reads (22%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs1170830864, COSV101190046; called by muse, mutect2, varscan2
- KCNT2 | c.3328C>G p.L1110V | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99655785, COSV99655921; called by muse, mutect2, varscan2
- KIAA1549 | c.2177C>A p.S726Y | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV99651646; called by muse, mutect2, varscan2
- KIF15 | c.3299T>A p.I1100N | Missense Mutation (SNP) | VAF 80/140 reads (57%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100393134; called by muse, mutect2, varscan2
- KIF19 | c.2983T>C p.S995P | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV100739147; called by muse, mutect2, varscan2
- KIF1B | c.2623A>C p.T875P (on ENST00000377086 / NM_001365952.1; = p.T829P on NM_015074.3) | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as COSV99823921; called by muse, mutect2, varscan2
- KIT | c.1718C>A p.P573Q | Missense Mutation (SNP) | VAF 73/129 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV55389178, COSV55391725, COSV99855014; called by muse, mutect2, varscan2
- KPRP | c.718T>A p.Y240N | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as rs752539096, COSV100908767; called by muse, mutect2, varscan2
- LCE1B | c.79C>G p.P27A | Missense Mutation (SNP) | VAF 162/333 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.198); catalogued as COSV100780244, COSV100780306; called by muse, mutect2, varscan2
- LDB2 | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 49/101 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1277170300, COSV58765241, COSV58766021; called by muse, mutect2, varscan2
- LGALS9B | c.491T>A p.F164Y | Missense Mutation (SNP) | VAF 100/395 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.205); catalogued as COSV100163022; called by muse, varscan2
- LRIG2 | c.1849G>T p.A617S | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.101); catalogued as COSV100743595; called by muse, mutect2
- LRRC4C | c.521T>C p.L174S | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99539181; called by muse, mutect2, varscan2
- LRRC6 | c.1214A>T p.Q405L | Missense Mutation (SNP) | VAF 42/265 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.035); catalogued as COSV99138382; called by muse, mutect2, varscan2
- MAP2K2 | c.448A>T p.M150L | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV53562900; called by muse, mutect2, varscan2
- MAPK10 | c.719A>T p.Q240L (on ENST00000359221 / NM_001351625.2; = p.Q278L on NM_002753.5) | Missense Mutation (SNP) | VAF 63/87 reads (72%) | SIFT tolerated (0.91); PolyPhen benign (0.017); catalogued as COSV100175147; called by muse, mutect2, varscan2
- MC2R | c.89T>C p.I30T | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as COSV100563132; called by muse, mutect2, varscan2
- METTL1 | c.389G>T p.G130V | Missense Mutation (SNP) | VAF 71/125 reads (57%) | SIFT tolerated (0.12); PolyPhen benign (0.14); catalogued as COSV99141624; called by muse, mutect2, varscan2
- MFSD4A | c.857T>A p.L286Q | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV100901674; called by muse, mutect2, varscan2
- MIEF1 | c.644G>T p.W215L | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100307564; called by muse, mutect2, varscan2
- MTF1 | c.1728A>C p.L576F | Missense Mutation (SNP) | VAF 70/149 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100888692; called by muse, mutect2, varscan2
- MYO10 | c.2197A>T p.K733* | Nonsense Mutation (SNP) | VAF 15/62 reads (24%) | catalogued as COSV99946006; called by muse, mutect2, varscan2
- N4BP2L2 | c.1655A>G p.H552R | Missense Mutation (SNP) | VAF 39/71 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV99912671; called by muse, mutect2, varscan2
- NBEA | c.5966T>A p.L1989* | Nonsense Mutation (SNP) | VAF 27/93 reads (29%) | catalogued as COSV100082936; called by muse, mutect2, varscan2
- NCS1 | c.118A>T p.S40C | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); catalogued as COSV100969999; called by muse, mutect2, varscan2
- NEB | c.2918A>T p.K973M | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99426282; called by muse, mutect2, varscan2
- NEIL3 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 15/264 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99220815; called by muse, mutect2
- NLRP2 | c.2074T>A p.C692S | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV99672536; called by muse, varscan2
- NOL12 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV100767162; called by muse, mutect2, varscan2
- NOS1 | c.3271C>G p.P1091A | Missense Mutation (SNP) | VAF 51/147 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755981500, COSV100501169, COSV57610437; called by muse, mutect2, varscan2
- NUF2 | c.39G>C p.E13D | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.017); catalogued as COSV99616758; called by muse, mutect2, varscan2
- NUP62 | c.611A>G p.Q204R | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.107); catalogued as COSV100352266; called by muse, mutect2, varscan2
- OBSCN | c.22708G>A p.A7570T | Missense Mutation (SNP) | VAF 39/158 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs370427130; called by muse, mutect2, varscan2
- OR11H4 | c.121T>C p.F41L | Missense Mutation (SNP) | VAF 51/164 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.121); catalogued as COSV100197582; called by muse, mutect2, varscan2
- OR51D1 | c.947T>A p.L316H | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.806); catalogued as COSV100712418; called by muse, mutect2, varscan2
- OR8K5 | c.883G>T p.E295* | Nonsense Mutation (SNP) | VAF 12/36 reads (33%) | catalogued as COSV100537278; called by muse, mutect2, varscan2
- P4HTM | c.983A>T p.H328L | Missense Mutation (SNP) | VAF 53/94 reads (56%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.575); catalogued as COSV100637597; called by muse, mutect2, varscan2
- PAN3 | c.551A>T p.Q184L | Missense Mutation (SNP) | VAF 19/27 reads (70%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.922); catalogued as COSV101111159; called by muse, mutect2, varscan2
- PCDHAC1 | c.2039A>T p.Q680L | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99167952; called by muse, mutect2, varscan2
- PCDHB2 | c.1440A>T p.R480S | Missense Mutation (SNP) | VAF 56/154 reads (36%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.01); catalogued as COSV99166128; called by muse, mutect2, varscan2
- PCLO | c.7175C>A p.P2392Q | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.193); catalogued as rs777900734, COSV100436071; called by muse, varscan2
- PITX1 | c.619C>G p.P207A | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as rs1450755660, COSV99530716; called by muse, mutect2, varscan2
- PLA2G2F | c.530T>A p.L177H | Missense Mutation (SNP) | VAF 74/177 reads (42%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.964); catalogued as COSV100907923; called by muse, mutect2, varscan2
- PLEKHG3 | c.2870A>T p.Q957L (on ENST00000394691; = p.Q1013L on NM_001308147.2) | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.03); catalogued as COSV99906954; called by muse, mutect2, varscan2
- PLXNB1 | c.3658A>T p.S1220C | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.926); catalogued as COSV99603250; called by muse, mutect2, varscan2
- PRDM16 | c.1583T>A p.L528Q | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV99578199; called by muse, mutect2, varscan2
- PRSS38 | c.40T>A p.S14T | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as COSV100816537; called by muse, mutect2, varscan2
- PSMB9 | c.451A>T p.S151C | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100841275; called by muse, mutect2, varscan2
- PTCH2 | c.256T>A p.W86R | Missense Mutation (SNP) | VAF 56/140 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100942233; called by muse, mutect2
- PZP | c.1093-2A>T p.X365_splice | Splice Site (SNP) | VAF 46/72 reads (64%) | catalogued as COSV99738953; called by muse, varscan2
- RAB3D | c.146C>T p.P49L | Missense Mutation (SNP) | VAF 50/68 reads (74%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.681); catalogued as rs1338861475, COSV99708930; called by muse, mutect2, varscan2
- RAPGEF1 | c.255A>C p.Q85H | Missense Mutation (SNP) | VAF 60/80 reads (75%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.976); catalogued as COSV100940699; called by muse, mutect2, varscan2
- RFTN2 | c.400G>A p.A134T | Missense Mutation (SNP) | VAF 72/128 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99695891; called by muse, mutect2
- RNF115 | c.832A>T p.T278S | Missense Mutation (SNP) | VAF 55/222 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0.056); catalogued as COSV100991874; called by muse, mutect2, varscan2
- SAGE1 | c.2486A>T p.Y829F | Missense Mutation (SNP) | VAF 28/34 reads (82%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV100187708; called by muse, mutect2, varscan2
- SAMD14 | c.994G>A p.G332S (on ENST00000330175 / NM_001257359.2; = p.G360S on NM_174920.4) | Missense Mutation (SNP) | VAF 39/134 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.435); catalogued as COSV99143046; called by muse, mutect2, varscan2
- SCN11A | c.1072del p.Q358Kfs*34 | Frame Shift Del (DEL) | VAF 19/90 reads (21%) | catalogued as COSV100181211; called by mutect2, pindel, varscan2
- SCNN1D | c.1118G>T p.G373V (on ENST00000338555; = p.G537V on NM_001130413.4) | Missense Mutation (SNP) | VAF 47/92 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV100330222; called by muse, mutect2, varscan2
- SDK1 | c.4448T>A p.L1483H | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs1468698192, COSV101269678; called by muse, mutect2, varscan2
- SEPTIN2 | c.760A>T p.R254* | Nonsense Mutation (SNP) | VAF 42/150 reads (28%) | catalogued as COSV100764976; called by muse, mutect2, varscan2
- SHOC1 | c.1193T>A p.I398K | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.219); catalogued as COSV100597947; called by muse, mutect2, varscan2
- SIAH1 | c.573A>T p.L191F | Missense Mutation (SNP) | VAF 56/70 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99589430; called by muse, varscan2
- SLC12A7 | c.3098A>G p.D1033G | Missense Mutation (SNP) | VAF 34/195 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV99370369; called by muse, mutect2, varscan2
- SLC24A2 | c.447A>T p.L149F | Missense Mutation (SNP) | VAF 26/32 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99647180; called by muse, mutect2, varscan2
- SLC24A5 | c.493T>A p.S165T | Missense Mutation (SNP) | VAF 47/57 reads (82%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.793); catalogued as COSV100165620; called by muse, mutect2, varscan2
- SLC36A3 | c.953C>A p.T318N | Missense Mutation (SNP) | VAF 45/103 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100077791; called by muse, mutect2, varscan2
- SLC39A4 | c.643A>T p.S215C (on ENST00000301305 / NM_001374839.1; = p.S190C on NM_017767.3) | Missense Mutation (SNP) | VAF 31/257 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV99433601; called by muse, mutect2, varscan2
- SLC8A1 | c.1720T>C p.Y574H | Missense Mutation (SNP) | VAF 54/95 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100247023; called by muse, mutect2, varscan2
- SULT1C4 | c.568A>T p.K190* | Nonsense Mutation (SNP) | VAF 52/89 reads (58%) | catalogued as COSV99731733; called by muse, mutect2, varscan2
- TBX20 | c.26C>A p.P9H | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV101282403; called by muse, mutect2, varscan2
- TCF7 | c.1087C>T p.P363S (on ENST00000395029; = p.P248S on NM_201634.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV100390109; called by muse, mutect2, varscan2
- TDRD5 | c.425T>A p.L142Q | Missense Mutation (SNP) | VAF 75/316 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99676850; called by muse, mutect2, varscan2
- TLE4 | c.1431T>A p.H477Q | Missense Mutation (SNP) | VAF 34/146 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.216); catalogued as COSV99512817; called by muse, mutect2, varscan2
- TMEM245 | c.1009A>T p.R337* | Nonsense Mutation (SNP) | VAF 52/83 reads (63%) | catalogued as COSV101002439; called by muse, mutect2, varscan2
- TMTC3 | c.429A>T p.R143S | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99898574; called by mutect2, varscan2
- TRMT2A | c.748G>A p.G250R | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs761732799, COSV99350185; called by muse, mutect2, varscan2
- TRPS1 | c.2496T>G p.N832K (on ENST00000220888 / NM_001330599.2; = p.N845K on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.344); catalogued as COSV99633307; called by muse, mutect2, varscan2
- UNC13C | c.1738T>A p.S580T | Missense Mutation (SNP) | VAF 27/33 reads (82%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as COSV99521546; called by muse, mutect2, varscan2
- UNC5D | c.752-2A>T p.X251_splice | Splice Site (SNP) | VAF 15/77 reads (19%) | catalogued as COSV99777725; called by muse, mutect2, varscan2
- USH2A | c.2684A>T p.Q895L | Missense Mutation (SNP) | VAF 58/221 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0.047); catalogued as COSV100239931; called by muse, mutect2, varscan2
- USP44 | c.729T>A p.D243E | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV99311986; called by muse, mutect2, varscan2
- VCAN | c.5851G>A p.E1951K | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.265); catalogued as COSV99426849; called by muse, mutect2, varscan2
- XDH | c.3122A>T p.Q1041L | Missense Mutation (SNP) | VAF 110/170 reads (65%) | SIFT deleterious (0.02); PolyPhen benign (0.132); catalogued as COSV101052417; called by muse, varscan2
- ZBBX | c.2182G>A p.D728N | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as COSV100284719, COSV56795334; called by muse, mutect2, varscan2
- ZNF286A | c.655A>T p.T219S | Missense Mutation (SNP) | VAF 39/73 reads (53%) | SIFT tolerated (0.6); PolyPhen benign (0.015); catalogued as COSV101224834; called by muse, mutect2, varscan2
- ZNF470 | c.423T>G p.C141W | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.057); catalogued as COSV100401347; called by muse, mutect2, varscan2
- ZNF581 | c.316A>T p.S106C | Missense Mutation (SNP) | VAF 79/159 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99553242; called by muse, mutect2, varscan2
- ZNF835 | c.1564T>A p.C522S | Missense Mutation (SNP) | VAF 55/137 reads (40%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0.036); catalogued as COSV101606391; called by muse, mutect2, varscan2
- ZNF91 | c.2771A>T p.H924L | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.463); catalogued as COSV100322319; called by muse, mutect2, varscan2
- ALPP | c.1122C>A p.S374R | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by mutect2, varscan2
- FBLN2 | c.2674_2675del p.R892Gfs*12 | Frame Shift Del (DEL) | VAF 49/89 reads (55%) | called by mutect2, pindel, varscan2
- IGHV3-23 | c.200T>A p.V67D | Missense Mutation (SNP) | VAF 48/337 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- IPO7 | c.2775del p.D926Mfs*55 | Frame Shift Del (DEL) | VAF 42/152 reads (28%) | called by mutect2, pindel, varscan2
- LRRK1 | c.5606_5607del p.V1869Afs*23 | Frame Shift Del (DEL) | VAF 48/84 reads (57%) | called by pindel, varscan2
- MRPL45 | c.869A>T p.E290V | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- NME6 | c.35del p.Q12Rfs*4 (on ENST00000415053; = p.Q20Rfs*4 on NM_005793.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 24/97 reads (25%) | called by mutect2, pindel, varscan2
- ADAMTS13 | c.1467C>T p.A489= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as COSV100747171; called by muse, varscan2
- ASH1L | c.3375A>T p.A1125= | Silent (SNP) | VAF 49/177 reads (28%) | catalogued as COSV100853556; called by muse, mutect2, varscan2
- ASNS | c.1092A>T p.G364= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV99446624; called by muse, mutect2, varscan2
- ASXL3 | c.2670A>T p.T890= | Silent (SNP) | VAF 20/48 reads (42%) | catalogued as COSV99326008; called by muse, mutect2, varscan2
- CACNA1S | c.612C>T p.L204= | Silent (SNP) | VAF 31/205 reads (15%) | catalogued as COSV100755241; called by muse, mutect2, varscan2
- CALCOCO1 | c.60A>T p.V20= | Silent (SNP) | VAF 135/227 reads (59%) | catalogued as COSV100017431; called by muse, mutect2, varscan2
- CHD7 | c.6351C>T p.L2117= | Silent (SNP) | VAF 47/170 reads (28%) | catalogued as COSV101418374; called by muse, mutect2, varscan2
- CSMD2 | c.7698C>T p.G2566= | Silent (SNP) | VAF 32/79 reads (41%) | catalogued as rs771706014, COSV53936624; called by muse, mutect2, varscan2
- CYLC1 | c.156G>A p.L52= | Silent (SNP) | VAF 32/52 reads (62%) | catalogued as rs770520850, COSV61416705; called by muse, mutect2, varscan2
- DNAH5 | c.6225T>A p.P2075= | Silent (SNP) | VAF 40/220 reads (18%) | catalogued as COSV99452620; called by muse, mutect2, varscan2
- DYNC2I1 | c.837A>G p.K279= | Silent (SNP) | VAF 67/174 reads (39%) | catalogued as COSV101337720; called by muse, mutect2, varscan2
- FASN | c.1200G>A p.V400= | Silent (SNP) | VAF 34/119 reads (29%) | catalogued as rs1330333245, COSV100148156; called by muse, varscan2
- FBLN2 | c.2670T>C p.F890= | Silent (SNP) | VAF 52/92 reads (57%) | catalogued as rs1392439901; called by mutect2, varscan2
- FLG | c.7731A>C p.S2577= | Silent (SNP) | VAF 66/291 reads (23%) | catalogued as COSV100911949; called by muse, mutect2, varscan2
- FRYL | c.7146A>G p.V2382= | Silent (SNP) | VAF 24/44 reads (55%) | catalogued as rs748361039, COSV99977724; called by muse, mutect2, varscan2
- FSCB | c.447A>G p.E149= | Silent (SNP) | VAF 99/154 reads (64%) | catalogued as COSV100469691; called by muse, mutect2, varscan2
- GAGE2A | c.39A>T p.P13= | Silent (SNP) | VAF 4/68 reads (6%) | called by muse, mutect2
- GLUL | c.1020T>C p.R340= | Silent (SNP) | VAF 38/188 reads (20%) | catalogued as COSV100092195; called by muse, mutect2, varscan2
- GPR158 | c.1254T>G p.L418= | Silent (SNP) | VAF 79/280 reads (28%) | catalogued as COSV100894127; called by muse, mutect2, varscan2
- GRIN2A | c.444A>T p.G148= | Silent (SNP) | VAF 16/27 reads (59%) | catalogued as COSV100410678; called by muse, mutect2, varscan2
- HAPLN2 | c.621T>A p.P207= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs763079436, COSV99661013; called by muse, mutect2, varscan2
- HIVEP2 | c.3453G>T p.L1151= | Silent (SNP) | VAF 33/86 reads (38%) | catalogued as COSV50008082; called by muse, mutect2, varscan2
- IFIH1 | c.2823A>G p.V941= | Silent (SNP) | VAF 15/34 reads (44%) | catalogued as COSV99718795; called by muse, mutect2
- IL18BP | c.339A>G p.R113= | Silent (SNP) | VAF 32/78 reads (41%) | catalogued as rs761365336, COSV99474917; called by muse, mutect2, varscan2
- ITIH4 | c.345T>C p.A115= | Silent (SNP) | VAF 75/162 reads (46%) | catalogued as COSV99819715; called by muse, mutect2, varscan2
- ITSN2 | c.3972T>C p.D1324= | Silent (SNP) | VAF 16/83 reads (19%) | catalogued as rs1188731987, COSV100744005; called by muse, mutect2, varscan2
- KLRC4 | c.270A>T p.T90= | Silent (SNP) | VAF 166/292 reads (57%) | catalogued as COSV100511341; called by muse, mutect2, varscan2
- LGR5 | c.1023A>T p.S341= | Silent (SNP) | VAF 86/166 reads (52%) | catalogued as COSV99878262; called by muse, mutect2, varscan2
- LMOD2 | c.597T>A p.I199= | Silent (SNP) | VAF 37/83 reads (45%) | catalogued as COSV101505441; called by muse, mutect2, varscan2
- LZTS1 | c.78C>T p.R26= | Silent (SNP) | VAF 24/95 reads (25%) | catalogued as rs1164846871, COSV99743208; called by muse, mutect2, varscan2
- MAP1B | c.5667T>C p.Y1889= | Silent (SNP) | VAF 26/45 reads (58%) | catalogued as COSV99702796; called by muse, mutect2, varscan2
- MAP3K6 | c.2877G>A p.P959= | Silent (SNP) | VAF 41/92 reads (45%) | catalogued as rs376956203; called by muse, mutect2, varscan2
- MSLNL | c.2043A>T p.S681= | Silent (SNP) | VAF 27/97 reads (28%) | catalogued as COSV99558559; called by muse, mutect2, varscan2
- NCKAP5L | c.1152T>C p.G384= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV100259086; called by muse, mutect2, varscan2
- NCR2 | c.510T>C p.S170= | Silent (SNP) | VAF 45/57 reads (79%) | catalogued as COSV100897249; called by muse, mutect2, varscan2
- NEIL3 | c.333T>C p.Y111= | Silent (SNP) | VAF 70/81 reads (86%) | catalogued as COSV99220822; called by muse, mutect2, varscan2
- NSD3 | c.4032A>C p.A1344= | Silent (SNP) | VAF 76/299 reads (25%) | catalogued as COSV100395582; called by muse, mutect2, varscan2
- OR4D9 | c.660C>A p.V220= | Silent (SNP) | VAF 34/73 reads (47%) | catalogued as COSV100259943; called by muse, mutect2, varscan2
- OR5R1 | c.288T>A p.A96= | Silent (SNP) | VAF 42/86 reads (49%) | catalogued as COSV100393539; called by muse, varscan2
- PMEPA1 | c.816A>T p.A272= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as COSV99671981; called by muse, mutect2, varscan2
- PSD2 | c.315A>T p.A105= | Silent (SNP) | VAF 30/57 reads (53%) | catalogued as COSV99217430; called by muse, mutect2, varscan2
- PUF60 | c.1305C>T p.S435= (on ENST00000526683 / NM_001362896.2; = p.S418= on NM_014281.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 10/127 reads (8%) | catalogued as rs372944670; called by muse, mutect2
- RALGAPA2 | c.2031A>T p.R677= | Silent (SNP) | VAF 22/94 reads (23%) | catalogued as COSV99174689; called by muse, mutect2, varscan2
- RHBDL3 | c.504A>T p.T168= | Silent (SNP) | VAF 99/170 reads (58%) | catalogued as COSV99283851; called by muse, mutect2, varscan2
- ROBO1 | c.1710A>T p.T570= | Silent (SNP) | VAF 33/109 reads (30%) | catalogued as COSV101459128; called by muse, mutect2, varscan2
- SDK1 | c.4734A>T p.P1578= | Silent (SNP) | VAF 35/83 reads (42%) | catalogued as COSV101269679; called by muse, mutect2, varscan2
- SEPTIN4 | c.369T>A p.V123= | Silent (SNP) | VAF 97/156 reads (62%) | catalogued as COSV100400416; called by muse, mutect2, varscan2
- SLC52A1 | c.837T>A p.G279= | Silent (SNP) | VAF 68/80 reads (85%) | catalogued as COSV99643501; called by muse, mutect2, varscan2
- SP7 | c.189T>A p.A63= | Silent (SNP) | VAF 23/60 reads (38%) | catalogued as COSV100382085; called by muse, mutect2, varscan2
- TBR1 | c.1248C>A p.R416= | Silent (SNP) | VAF 27/86 reads (31%) | catalogued as COSV101271516; called by muse, varscan2
- TIAM2 | c.3699C>T p.P1233= | Silent (SNP) | VAF 59/72 reads (82%) | catalogued as COSV99265871; called by muse, varscan2
- EIF3F | c.*531A>T | 3'UTR (SNP) | VAF 14/55 reads (25%) | catalogued as COSV100562633; called by muse, mutect2, varscan2
- MORF4 | n.677C>A | RNA (SNP) | VAF 145/168 reads (86%) | called by muse, mutect2, varscan2
- OBSCN | c.4585+2802dup | Intron (INS) | VAF 51/187 reads (27%) | called by mutect2, pindel, varscan2
- P4HA1 | c.1148+1079_1148+1095del | Intron (DEL) | VAF 24/35 reads (69%) | called by mutect2, pindel, varscan2
- RXRG | c.49+7648T>C | Intron (SNP) | VAF 29/143 reads (20%) | catalogued as rs372062757; called by muse, mutect2, varscan2
- SSPOP | n.15644A>T | RNA (SNP) | VAF 16/37 reads (43%) | catalogued as COSV100947845; called by muse, mutect2, varscan2
